Gene-level copy-number profile of tumor specimen C3L-03367-01 from CPTAC case C3L-03367, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 71.6 years (26,149 days).
Specimen C3L-03367-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 59cc53ec-f97e-4039-81ef-a92453f07fce.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03367-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/0380ddd4-847f-4043-a25b-c3fa6ed38b89

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 4,570; copy number 2: 38,812; copy number 3: 14,344; copy number 4: 201; copy number 5: 195; copy number 6: 157; copy number 7: 122; copy number 8: 66; copy number 9: 55; copy number 10: 85; copy number 11: 34; copy number 12: 35; copy number 13: 36; copy number 14: 11; copy number 15: 23; copy number 16: 12; copy number 17: 21; copy number 18: 16; copy number 19: 1; copy number 20: 27; copy number 21: 10; copy number 22: 3; copy number 23: 12; copy number 24: 3; copy number 25: 8; copy number 27: 4; copy number 28: 4.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–143,739,506, 8 genes: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2.
- chr1:143,766,540–144,305,180, 20 genes: FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1.
- chr1:149,700,151–149,700,296, 1 gene (within-gene range 0–1): RNU1-68P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 940 genes in 57 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:54,603,211–59,180,414, 83 genes, copy number 5 (broad region; genes not listed).
- chr5:92,151–1,295,068, 45 genes, copy number 7–20: PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr5:6,448,859–6,600,288, 3 genes, copy number 13 (within-gene range 2–13): UBE2QL1, AC027334.1, LINC01018.
- chr5:17,490,967–17,655,849, 28 genes, copy number 9: H3Y2, AC106774.1, TAF11L2, H3P17, H3P18, TAF11L3, TAF11L4, TAF11L5, TAF11L6, TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1.
- chr5:31,400,497–32,888,145, 35 genes, copy number 10–20: DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, NPR3, AC025459.1.
- chr5:34,158,121–39,524,726, 89 genes, copy number 6–28 (broad region; genes not listed).
- chr5:43,192,071–43,280,850, 4 genes, copy number 13: NIM1K, AC106800.1, AC106800.2, TUBAP14.
- chr12:42,361,267–43,572,038, 21 genes, copy number 8–17: AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2.
- chr12:43,835,967–45,117,888, 12 genes, copy number 6: TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361.
- chr12:53,441,741–53,677,408, 15 genes, copy number 5 (within-gene range 2–5): AC023509.1, PCBP2, PCBP2-OT1, AC023509.4, MAP3K12, AC023509.3, TARBP2, ATF7-NPFF, NPFF, ATF7, AC023509.2, AC023509.6, AC023509.5, ATP5MC2, AC073594.1.
- chr12:53,954,903–53,977,643, 7 genes, copy number 6: HOXC12, HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6, HOXC11.
- chr12:55,314,343–56,038,435, 53 genes, copy number 7–10 (within-gene range 4–10): OR6C1, OR6C3, OR6C7P, OR6C75, OR6C71P, OR6C66P, OR6C73P, OR6C65, PHC1P1, OR6C76, AC122685.1, OR6C2, OR6C70, OR6C68, OR6C64P, OR6C4, OR2AP1, OR6U2P, OR10P1, AC009779.4, OR10AE3P, PSMB3P1, AC009779.5, METTL7B, ITGA7, AC009779.3, BLOC1S1, RDH5, CD63, AC009779.2, Metazoa_SRP, AC009779.1, GDF11, SARNP, AC023055.1, AC073487.1, ORMDL2, DNAJC14, TMEM198B, MMP19, OLA1P3, GSTP1P1, PYM1, DGKA, AC025162.2, PMEL, CDK2, AC025162.1, RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8.
- chr12:56,285,916–57,846,729, 98 genes, copy number 6–18 (within-gene range 2–18) (broad region; genes not listed).
- chr12:61,600,067–62,279,150, 5 genes, copy number 7–9 (within-gene range 3–11): DUX4L52, TAFA2, RPL21P104, KRT8P19, RPS3P6.
- chr12:63,779,842–64,507,329, 25 genes, copy number 6 (within-gene range 4–6): RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P, C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1.
- chr12:64,507,166–64,609,459, 3 genes, copy number 6: AC078962.2, SNORD83, AC078962.4.
- chr12:65,758,020–65,966,291, 5 genes, copy number 9: RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:66,950,754–67,132,205, 3 genes, copy number 5–7: AC073530.1, AC073530.2, RAB11AP2.
- chr12:67,443,105–67,978,387, 8 genes, copy number 7–12: LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1.
- chr12:68,805,011–69,224,242, 10 genes, copy number 5–8: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1.
- chr12:69,470,349–70,243,379, 13 genes, copy number 7–8 (within-gene range 2–8): FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1.
- chr12:75,020,969–75,984,015, 18 genes, copy number 6–8 (within-gene range 2–8): AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1.
- chr12:76,259,836–77,317,234, 17 genes, copy number 5–8: LNCOG, RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7, LINC02464.
- chr12:78,326,680–81,261,210, 39 genes, copy number 5–24 (within-gene range 2–24): LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2, SYT1, AC090709.1, AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1, RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699.
- chr12:81,868,368–83,152,190, 12 genes, copy number 6–7: AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, TMTC2, RNU6-977P, RPL6P25.
- chr12:85,280,220–85,568,239, 3 genes, copy number 6–16: ALX1, LINC02820, AC126471.1.
- chr12:111,443,485–111,902,222, 14 genes, copy number 5 (within-gene range 1–5): ATXN2, U7, IFITM3P5, ATXN2-AS, BRAP, PCNPP1, ACAD10, AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A.
- chr12:112,125,538–113,480,624, 37 genes, copy number 5–22: TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11, RPH3A, MIR1302-1, OAS1, AC004551.1, OAS3, OAS2, IMMP1LP2, RPS15AP32, DTX1, RASAL1, CFAP73, Y_RNA, DDX54, MIR7106, Y_RNA, RITA1, AC089999.1, IQCD, TPCN1, AC089999.2, MIR6762, SLC8B1, PLBD2, SDS, SDSL, LHX5, LHX5-AS1.
- chr12:114,353,911–114,505,187, 3 genes, copy number 7: TBX5, TBX5-AS1, RN7SKP216.
- chr12:115,569,394–117,190,471, 37 genes, copy number 5–12: AC009803.2, AC009803.1, UBA52P7, RN7SL865P, AC009387.1, LINC02463, AC012157.1, AC012157.3, MED13L, AC012157.2, RNU6-1188P, MIR620, SNRPGP18, AC130895.1, AC079384.1, MIR4472-2, LINC02457, LINC00173, MAP1LC3B2, AC125603.4, AC125603.3, AC125603.2, AC125603.1, SPRING1, RNFT2, AC090013.1, RNU6-558P, AC083806.3, HRK, AC083806.1, FBXW8, AC083806.2, AC127164.1, AC026368.1, TESC, TESC-AS1, FBXO21.
- chr12:118,149,801–118,418,033, 4 genes, copy number 10–12 (within-gene range 1–12): TAOK3, RPS2P5, AC026367.1, SUDS3.
- chr12:119,361,247–119,877,320, 7 genes, copy number 7–10 (within-gene range 1–10): AC002070.1, TMEM233, RN7SKP197, PRKAB1, CIT, AC002563.1, MIR1178.
- chr12:120,369,440–120,577,588, 16 genes, copy number 5: RPS27P25, AC003982.1, COX6A1, AL021546.1, TRIAP1, GATC, RPL31P52, SRSF9, DYNLL1, NRAV, AC063943.1, COQ5, Y_RNA, RPL29P24, RNF10, AC063943.2.
- chr12:122,714,756–124,088,594, 61 genes, copy number 5–17 (within-gene range 1–17) (broad region; genes not listed).
- chr12:124,593,181–125,164,918, 19 genes, copy number 8–13: AC073592.8, AC073592.2, AC073592.10, AC073592.4, AC073593.1, SCARB1, AC073593.2, RNU6-927P, UBC, MIR5188, RPL22P19, DHX37, BRI3BP, THRIL, AC122688.1, AACS, AC122688.3, AC122688.2, AC122688.4.
- chr12:127,758,832–127,983,854, 6 genes, copy number 5: AC087894.3, AC087894.2, AC087894.1, LINC02393, LINC00507, LINC00508.
- chr12:128,793,194–129,016,663, 6 genes, copy number 5: SLC15A4, AC108704.2, AC108704.1, GLT1D1, AC069262.1, NLRP9P1.
- chr12:130,465,008–131,237,523, 22 genes, copy number 6–16: AC063926.2, AC095350.1, AC073912.3, STX2, AC073912.1, AC073912.2, RNU6-1077P, RAN, Y_RNA, ADGRD1, AC073862.3, AC073862.4, AC073862.5, AC073862.1, AC073862.2, AC078925.4, ADGRD1-AS1, AC078925.2, AC078925.3, AC078925.1, LINC01257, AC126564.1.
- chr12:131,347,470–131,529,894, 7 genes, copy number 8–13: LINC02370, AC140118.2, AC140118.1, AC073578.4, AC073578.2, AC073578.1, AC073578.3.
- chr12:131,639,396–132,131,639, 22 genes, copy number 7 (within-gene range 2–7): LINC02414, AC117500.4, RNA5SP377, AC117500.1, RPS6P21, SFSWAP, AC117500.2, RNA5SP378, RNU6-1017P, MMP17, AC131009.2, ULK1, AC131009.4, AC131009.1, PUS1, AC131009.3, EP400, SNORA49, AC137590.1, AC137590.2, EP400P1, AC138466.5.

Autosomal genes at a single copy (total copy number 1): 2,232. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
